Somatic mutation profile of tumor specimen MMRF_1342_1_BM_CD138pos (aliquot MMRF_1342_1_BM_CD138pos_T1_KAS5U_L00647) from MMRF case MMRF_1342, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.8 years (29,514 days).
Specimen MMRF_1342_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b47c99b-b27a-440f-82f7-67e807c169dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1342_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1342_1_PB_Whole_C2_KAS5U_L00655; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3a00cf1-0da9-44f4-b359-1c05c63e891a

The open-access MAF lists 153 somatic variants for this specimen: 59 protein-altering or splice-affecting, 15 silent, 79 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 43, Intron 18, Silent 15, 3'Flank 6, 5'UTR 5, RNA 4, Nonsense Mutation 4, Frame Shift Del 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 17/19 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.4567G>T p.D1523Y (on ENST00000506720 / NM_001322402.2; = p.D1412Y on NM_015236.6) | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV72229491; called by muse, mutect2, varscan2
- ALG8 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs1042120807; called by muse, mutect2, varscan2
- AOC2 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1336868658; called by muse, mutect2, varscan2
- ARMC9 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs778877264; called by muse, mutect2, varscan2
- CACNA1I | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60813166; called by muse, varscan2
- CDH19 | c.2305C>T p.Q769* | Nonsense Mutation (SNP) | VAF 48/88 reads (55%) | catalogued as COSV50954295; called by muse, mutect2, varscan2
- CLSTN3 | c.2011C>G p.Q671E | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99867879; called by muse, mutect2, varscan2
- HECW1 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV101222497; called by muse, mutect2
- IRF2BP1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1233425272, COSV56193225; called by muse, mutect2, varscan2
- KLHL36 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187198156; called by muse, mutect2, varscan2
- LRRC43 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs558151255; called by muse, mutect2, varscan2
- NUP210 | c.3001G>A p.V1001M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757686840, COSV54414340; called by muse, mutect2, varscan2
- POU4F2 | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV99850634; called by muse, mutect2, varscan2
- SLC5A2 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769636319; called by muse, mutect2, varscan2
- SMC4 | c.586_589del p.V196Ifs*3 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1172138157; called by mutect2, pindel
- TRIM29 | c.1576T>G p.S526A | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs753677905; called by muse, mutect2, varscan2
- WDFY4 | c.4694A>T p.E1565V | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57429849; called by muse, mutect2, varscan2
- WDR33 | c.354_358del p.K119Sfs*6 | Frame Shift Del (DEL) | VAF 80/151 reads (53%) | catalogued as rs1241486657; called by pindel, varscan2
- WT1 | c.1223C>A p.P408Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100187606; called by muse, mutect2, varscan2
- ZFHX2 | c.5011G>A p.G1671S | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.06); catalogued as rs368892129; called by muse, mutect2, varscan2
- ADCY6 | c.3016C>T p.R1006W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AMER1 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKS6 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CARMIL2 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC88B | c.2845G>T p.E949* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | called by muse, varscan2
- CCDC93 | c.1369T>A p.Y457N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- CD19 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- CD19 | c.819G>C p.E273D | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CEP350 | c.2088C>G p.D696E | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLSTN3 | c.2194C>T p.Q732* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- CRELD1 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRTAM | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DHX37 | c.2636G>T p.G879V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ELF1 | c.1587T>A p.S529R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- EPN1 | c.1471C>T p.P491S (on ENST00000270460 / NM_001321263.1; = p.P465S on NM_013333.3) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GNL3 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- IGF1R | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IREB2 | c.571del p.S191Lfs*25 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by pindel, varscan2
- KCNB2 | c.1424C>A p.S475Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MXRA5 | c.2279A>G p.E760G | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MYH2 | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- NXPH2 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR2H1 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OR2M3 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- P2RX2 | c.1334C>G p.S445* (on ENST00000343948 / NM_170683.4; = p.S347* on NM_012226.5) | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- PFN3 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- PPP1R9A | c.3249G>C p.K1083N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- PROX1 | c.1202A>T p.N401I | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PSMD3 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RBM17 | c.1202T>C p.V401A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- RBM33 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- SCN8A | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 90/146 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SHANK1 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SI | c.3397A>T p.M1133L | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ZBTB34 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF24 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF331 | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF629 | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AOC2 | c.75G>T p.L25= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as rs780332116; called by muse, mutect2, varscan2
- BSCL2 | c.804C>T p.F268= | Silent (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- BSN | c.1689G>A p.Q563= | Silent (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- CFAP54 | c.8754G>A p.T2918= | Silent (SNP) | VAF 44/72 reads (61%) | catalogued as rs1026612497, COSV73047667; called by muse, mutect2, varscan2
- CLSTN3 | c.1920C>T p.A640= | Silent (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- CLSTN3 | c.2259C>T p.I753= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs989037525; called by muse, varscan2
- CNTLN | c.3708G>A p.E1236= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- GPATCH3 | c.930G>A p.V310= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs939286764; called by muse, mutect2, varscan2
- IGF1R | c.2061C>G p.P687= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- MAPK8 | c.1222T>C p.L408= | Silent (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- PHYKPL | c.1269G>T p.R423= | Silent (SNP) | VAF 28/40 reads (70%) | called by muse, varscan2
- SLC26A4 | c.1071T>G p.A357= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- SLC38A10 | c.489G>A p.V163= | Silent (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- SLC39A5 | c.1518G>A p.T506= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs781780136, COSV99907509; called by muse, mutect2, varscan2
- TTN | c.62106G>A p.K20702= (on ENST00000591111; = p.K13278= on NM_003319.4) | Silent (SNP) | VAF 36/65 reads (55%) | catalogued as COSV60090667; called by muse, mutect2, varscan2
- AC011525.1 | n.915G>A | RNA (SNP) | VAF 64/94 reads (68%) | catalogued as rs879683632; called by muse, mutect2, varscan2
- AJUBA | c.-160T>C | 5'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ALB | c.*88G>A | 3'UTR (SNP) | VAF 23/58 reads (40%) | catalogued as rs11538204; called by muse, mutect2, varscan2
- ARHGEF16 | c.1626-48G>A | Intron (SNP) | VAF 18/35 reads (51%) | catalogued as rs752680379; called by muse, mutect2, varscan2
- BMPR2 | c.*6149G>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CCDC198 | c.*592T>A | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- CMTM4 | c.*2333G>T | 3'UTR (SNP) | VAF 34/54 reads (63%) | called by muse, mutect2, varscan2
- COL27A1 | c.*1331G>T | 3'UTR (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- CPEB2 | chr4:15068518 T>C | 3'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- CPT2 | c.-113T>A | 5'UTR (SNP) | VAF 7/14 reads (50%) | catalogued as rs1279587051; called by muse, mutect2, varscan2
- CREBZF | c.*456G>C | 3'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- CREBZF | c.*308G>A | 3'UTR (SNP) | VAF 19/293 reads (6%) | called by muse, mutect2
- CRISPLD1 | c.*989dup | 3'UTR (INS) | VAF 12/21 reads (57%) | catalogued as rs942376769; called by mutect2, varscan2
- CSRNP3 | c.*1778T>C | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- CTBS | c.*748_*752del | 3'UTR (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- DBNL | c.*2998T>A | 3'UTR (SNP) | VAF 13/30 reads (43%) | catalogued as rs945574058; called by muse, mutect2, varscan2
- DYNC1H1 | c.8637+161T>G | Intron (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- EHD1 | chr11:64878760 T>A | 5'Flank (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- EPS8 | c.1102-66T>C | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2
- ERBB4 | c.*4593C>T | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- EYA1 | c.273-43C>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- FRAS1 | c.*1444T>A | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- GABRG2 | chr5:162067593 A>C | 5'Flank (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- GRIK2 | c.1748+366G>A | Intron (SNP) | VAF 14/14 reads (100%) | catalogued as rs923444717; called by muse, mutect2, varscan2
- GSK3B | c.1097-70T>A | Intron (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1598G>A | RNA (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- HOXC11 | c.*625C>A | 3'UTR (SNP) | VAF 25/90 reads (28%) | called by muse, mutect2, varscan2
- HYDIN2 | n.8720C>T | RNA (SNP) | VAF 19/56 reads (34%) | catalogued as rs1408179737; called by muse, mutect2, varscan2
- IKZF2 | c.-119-83T>A | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- INSL4 | c.*616C>T | 3'UTR (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- ITSN1 | c.*1450T>G | 3'UTR (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- KDM5A | c.*4928G>T | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4899+82T>C | Intron (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2
- KRT74 | c.*867C>G | 3'UTR (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- KRTAP3-2 | c.*115G>A | 3'UTR (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- KRTAP4-3 | c.*97G>A | 3'UTR (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- LCK | c.188-68C>T | Intron (SNP) | VAF 62/108 reads (57%) | called by muse, mutect2, varscan2
- LINC02872 | n.3174T>C | RNA (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- MBNL3 | chrX:132376433 A>C | 3'Flank (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- MEF2A | c.*3338dup | 3'UTR (INS) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- MIRLET7BHG | n.309-3348G>A | Intron (SNP) | VAF 6/16 reads (38%) | catalogued as rs1569160656; called by muse, mutect2, varscan2
- MPPED2 | c.*771C>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | catalogued as rs1461723770; called by muse, mutect2, varscan2
- MS4A7 | c.*1357G>A | 3'UTR (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- MYO5A | c.*5438_*5439del | 3'UTR (DEL) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- NLGN1 | c.*1836dup | 3'UTR (INS) | VAF 10/25 reads (40%) | catalogued as rs886951308; called by mutect2, varscan2
- NUDT16 | c.*1484T>C | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- NXNL1 | c.-35C>T | 5'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as rs200603341, COSV57325119; called by muse, mutect2, varscan2
- OTUB1 | chr11:63997761 C>T | 3'Flank (SNP) | VAF 11/39 reads (28%) | catalogued as rs924940220, COSV55362242; called by muse, mutect2, varscan2
- OXCT1 | c.*1314G>A | 3'UTR (SNP) | VAF 30/47 reads (64%) | catalogued as rs970641432; called by muse, mutect2, varscan2
- PAX9 | c.*1118G>A | 3'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- PITX2 | c.390+993A>T | Intron (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- PLA2G4E | c.*1709G>A | 3'UTR (SNP) | VAF 21/61 reads (34%) | catalogued as rs888008726; called by muse, mutect2, varscan2
- POLE | c.*611G>C | 3'UTR (SNP) | VAF 6/41 reads (15%) | called by muse, varscan2
- PPFIA4 | c.*742T>A | 3'UTR (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- PTPRO | chr12:15322388 C>T | 5'Flank (SNP) | VAF 5/16 reads (31%) | called by muse, varscan2
- PTPRR | c.628-235G>A | Intron (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2
- PXT1 | c.301-26C>A | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, varscan2
- RECK | c.637+1709C>T | Intron (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- RHEB | c.-222C>T | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- RMI2 | c.*710C>T | 3'UTR (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- RNF7 | c.176-789A>T | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- RPRD2 | chr1:150474893 G>A | 3'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- RPS9 | c.408-265T>G | Intron (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153419551 G>T | 3'Flank (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- SAMD13 | chr1:84350752 T>G | 3'Flank (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- SIPA1L3 | c.*58C>G | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- SIRT1 | c.*1562A>G | 3'UTR (SNP) | VAF 9/17 reads (53%) | catalogued as rs949776915; called by muse, mutect2, varscan2
- SMARCE1 | c.*2391A>C | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- SPTLC1 | c.427+44G>A | Intron (SNP) | VAF 34/147 reads (23%) | catalogued as rs752598429; called by muse, mutect2, varscan2
- ST6GAL1 | c.*1752C>G | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2
- SYT17 | c.*524T>A | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- TBL3 | c.-74G>T | 5'UTR (SNP) | VAF 44/58 reads (76%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*3125G>A | 3'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- THSD4 | c.*4000G>T | 3'UTR (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- TMEM132B | c.*4713A>T | 3'UTR (SNP) | VAF 19/25 reads (76%) | called by muse, mutect2, varscan2
- TSEN54 | c.*215G>T | 3'UTR (SNP) | VAF 8/13 reads (62%) | catalogued as rs1023306063; called by muse, varscan2
- TUSC2 | c.*1045A>G | 3'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- WDR72 | c.*267T>A | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- ZNF382 | c.-13-108A>G | Intron (SNP) | VAF 46/153 reads (30%) | called by muse, mutect2, varscan2
